Somatic mutation profile of tumor specimen MP2PRT-PASIMZ-TMP1-A (aliquot MP2PRT-PASIMZ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASIMZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 2.7 years (1,002 days).
Specimen MP2PRT-PASIMZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37346123-5c44-446c-bd70-c37af4db864a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIMZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIMZ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94cd169d-2461-468a-b833-ac74f366a998

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIB2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 66/296 reads (22%) | catalogued as rs201845656, CM164140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011455.2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 33/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs376256589; called by muse, mutect2
- CACNA1H | c.5773C>T p.L1925F | Missense Mutation (SNP) | VAF 160/819 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1366597055; called by muse, mutect2, varscan2
- ECEL1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 103/557 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV58811073; called by muse, mutect2, varscan2
- KBTBD13 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 161/821 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs757520982; called by muse, mutect2, varscan2
- OR2M3 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101513405; called by muse, mutect2
- FAT1 | c.5153C>T p.T1718I | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- IGHV5-51 | chr14:106578734 TCACTGTGTGTCTC>CCCGTCAGGG | Missense Mutation (DEL) | VAF 68/128 reads (53%) | called by pindel, varscan2*
- IGKV1-5 | chr2:88947286 GTGTAACACTGTGGGAGAA>AAGG | Missense Mutation (DEL) | VAF 4/49 reads (8%) | called by pindel, varscan2*
- PEG10 | c.812C>T p.T271I (on ENST00000482108 / NM_001040152.2; = p.T305I on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/802 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZKSCAN7 | c.2120T>A p.I707N | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2
- ARID1B | c.3468C>T p.T1156= | Silent (SNP) | VAF 48/565 reads (8%) | catalogued as rs369218715; called by muse, mutect2
- ESRRG | c.108G>A p.S36= | Silent (SNP) | VAF 89/516 reads (17%) | catalogued as rs752362344; called by muse, mutect2, varscan2
- LIN7A | c.141G>T p.V47= | Silent (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- MKRN3 | c.312T>A p.I104= | Silent (SNP) | VAF 53/242 reads (22%) | called by muse, mutect2, varscan2
- ORM1 | c.174G>A p.S58= | Silent (SNP) | VAF 106/584 reads (18%) | catalogued as rs11552129; called by muse, varscan2
- PPP4R3C | c.90C>A p.T30= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- RBMXL2 | c.750C>T p.D250= | Silent (SNP) | VAF 161/763 reads (21%) | catalogued as rs757089818; called by muse, mutect2, varscan2
